Somatic mutation profile of tumor specimen 0DI7VB from CCDI case PBBVIK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.7 years (4,268 days).
Specimen 0DI7VB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 69334b22-a5bc-408c-88ca-4cb02fafadc4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI7VG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b4e9ad0e-a5c1-4a6d-8a83-bd24ac4f6121

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 7, Intron 2, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3-3A | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 212/556 reads (38%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.697); catalogued as rs1057519903, COSV64731746, COSV64731769; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.503A>G p.H168R | Missense Mutation (SNP) | VAF 356/410 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs867114783, COSV52676197, COSV52682212, COSV52698349, COSV52762255; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- BEND2 | c.1618G>T p.A540S | Missense Mutation (SNP) | VAF 253/288 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV66217387; called by muse, mutect2, varscan2
- CUL9 | c.1115G>A p.R372H | Missense Mutation (SNP) | VAF 273/635 reads (43%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.745); catalogued as rs373211287; called by muse, mutect2, varscan2
- DHX38 | c.3658C>T p.R1220C | Missense Mutation (SNP) | VAF 370/450 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs766544740; called by muse, varscan2
- FCRL3 | c.1247G>A p.R416Q | Missense Mutation (SNP) | VAF 262/551 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs375378164, COSV100942769, COSV63839727; called by muse, mutect2, varscan2
- NFKBIZ | c.1337C>T p.T446M | Missense Mutation (SNP) | VAF 152/339 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs759341204, COSV100397049; called by muse, mutect2, varscan2
- XPO6 | c.2970G>T p.Q990H | Missense Mutation (SNP) | VAF 53/1030 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs754247567; called by muse, mutect2
- ZNF541 | c.388C>T p.R130W | Missense Mutation (SNP) | VAF 307/681 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1449858181, COSV54543770; called by muse, mutect2, varscan2
- ADAM28 | c.1584T>G p.D528E | Missense Mutation (SNP) | VAF 106/1070 reads (10%) | SIFT tolerated (0.59); PolyPhen benign (0.11); called by muse, mutect2
- DNAH5 | c.7625G>T p.W2542L | Missense Mutation (SNP) | VAF 302/746 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRAMD1A | c.1853G>A p.S618N | Missense Mutation (SNP) | VAF 258/553 reads (47%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- INTS6L | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 307/349 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- OR2T11 | c.789C>A p.H263Q | Missense Mutation (SNP) | VAF 384/979 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4P4 | c.525C>A p.Y175* | Nonsense Mutation (SNP) | VAF 62/506 reads (12%) | called by mutect2, varscan2
- PHF24 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 123/1056 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ROBO1 | c.1373G>C p.R458P | Missense Mutation (SNP) | VAF 318/770 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TECPR2 | c.3158C>T p.A1053V | Missense Mutation (SNP) | VAF 134/429 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TSHZ2 | c.1040A>T p.Q347L | Missense Mutation (SNP) | VAF 512/1622 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ZNF875 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 203/469 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CEP120 | c.75G>A p.K25= | Silent (SNP) | VAF 272/631 reads (43%) | catalogued as rs1462581352; called by muse, mutect2, varscan2
- ELFN1 | c.1158C>T p.A386= | Silent (SNP) | VAF 327/802 reads (41%) | catalogued as rs756352333, COSV70033755; called by muse, mutect2, varscan2
- GFY | c.1317C>A p.P439= | Silent (SNP) | VAF 141/698 reads (20%) | called by muse, mutect2, varscan2
- GRIK5 | c.2229C>T p.L743= | Silent (SNP) | VAF 201/507 reads (40%) | catalogued as rs879971267; called by muse, mutect2, varscan2
- MUC16 | c.21330C>A p.P7110= | Silent (SNP) | VAF 394/816 reads (48%) | catalogued as COSV67465154; called by muse, mutect2, varscan2
- MYO16 | c.1455C>T p.F485= | Silent (SNP) | VAF 123/724 reads (17%) | called by muse, mutect2, varscan2
- RILPL1 | c.522C>T p.R174= | Silent (SNP) | VAF 470/1030 reads (46%) | catalogued as rs550802261, COSV61552733; called by muse, mutect2, varscan2
- GABRD | c.1060-52G>C | Intron (SNP) | VAF 87/213 reads (41%) | called by muse, mutect2, varscan2
- PHLDB1 | c.356-103_356-97del | Intron (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- PMFBP1 | c.*7G>T | 3'UTR (SNP) | VAF 134/169 reads (79%) | called by muse, mutect2, varscan2
